Somatic mutation profile of tumor specimen TARGET-10-PAUAZV-09A (aliquot TARGET-10-PAUAZV-09A-01D) from TARGET case TARGET-10-PAUAZV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,039 days).
Specimen TARGET-10-PAUAZV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97d749d4-0728-48a7-b3e6-698771c0f207.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUAZV-10A (Blood Derived Normal), aliquot TARGET-10-PAUAZV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53dc64c8-c459-498c-9ae5-6a059e4f679b

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 66/165 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- CCND3 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57829382; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- PCARE | c.3104G>A p.S1035N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs1285258737, COSV59057012; called by muse, mutect2, varscan2
- SORBS2 | c.527C>T p.P176L (on ENST00000284776 / NM_021069.5; = p.P222L on NM_003603.6) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs751304189, COSV53011503; called by muse, mutect2, varscan2
- SPICE1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as COSV55623898; called by muse, mutect2, varscan2
- NOTCH1 | c.7550dup p.D2518* | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- PIR | c.827dup p.N276Kfs*4 | Frame Shift Ins (INS) | VAF 38/69 reads (55%) | called by mutect2, pindel, varscan2
- ALOX5 | c.666G>A p.R222= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV65552596; called by muse, mutect2, varscan2
- NCOA2 | c.792T>G p.L264= | Silent (SNP) | VAF 65/144 reads (45%) | called by muse, mutect2, varscan2
- PITPNM2 | c.1590A>G p.T530= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- TENM2 | c.1320G>A p.S440= (on ENST00000518659 / NM_001122679.2; = p.S208= on NM_001080428.3) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs376153373, COSV69134057; called by muse, mutect2
- GRIA4 | c.2544+82G>A | Intron (SNP) | VAF 49/102 reads (48%) | catalogued as rs758682388, COSV56914178; called by muse, mutect2, varscan2
